Somatic mutation profile of tumor specimen 0DWNTW from CCDI case PBCPKH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.0 years (4,764 days).
Specimen 0DWNTW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63b1fce4-7779-4fc3-97e2-00c0484257bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWNR7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55a7e425-442c-423a-b8c6-fb20b00c202b

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B4GALNT2 | c.1471C>T p.R491C | Missense Mutation (SNP) | VAF 57/690 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs767487284, COSV100302699; called by muse, mutect2
- MUC5AC | c.5348G>A p.R1783Q | Missense Mutation (SNP) | VAF 88/1160 reads (8%) | SIFT tolerated (0.36); catalogued as rs1396754099; called by muse, mutect2
- IER5L | c.1129C>T p.Q377* | Nonsense Mutation (SNP) | VAF 50/732 reads (7%) | called by muse, mutect2
- LRWD1 | c.242T>G p.L81R | Missense Mutation (SNP) | VAF 29/614 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- OTUD7B | c.2346C>T p.P782= | Silent (SNP) | VAF 16/460 reads (3%) | catalogued as COSV100967534; called by muse, mutect2
- ZNF696 | c.612G>A p.T204= | Silent (SNP) | VAF 33/583 reads (6%) | catalogued as COSV57524580; called by muse, mutect2
- TRHDE | c.779+97A>G | Intron (SNP) | VAF 6/79 reads (8%) | called by muse, mutect2
